CCDI case PBBYRV — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c7ed238b-439e-4d9b-8e95-be0825b5cd8b

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.8 years (9,431 days).

Biospecimens (3 samples)
- Sample 0DLHO6: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DLHOG: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DLHOX: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
